Somatic mutation profile of tumor specimen 0DXCUB from CCDI case PBCPRS, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Malignant peripheral nerve sheath tumor with rhabdomyoblastic differentiation; Tissue or organ of origin: Mediastinum, NOS; Age at diagnosis: 21.6 years (7,900 days).
Specimen 0DXCUB: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8c82bf1c-9cf0-41cb-963f-fcca665a96be.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DXCTZ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ef8646f3-d5e8-4a22-8663-bffea8a9d99c

The open-access MAF lists 38 somatic variants for this specimen: 22 protein-altering or splice-affecting, 7 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 7, Intron 4, 3'UTR 3, Splice Region 2, Nonsense Mutation 2, Frame Shift Del 2, 5'UTR 2, Splice Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CCDC116 | c.1031C>G p.S344* | Nonsense Mutation (SNP) | VAF 226/710 reads (32%) | catalogued as COSV99489532; called by muse, varscan2
- MLPH | c.192C>A p.C64* | Nonsense Mutation (SNP) | VAF 266/1030 reads (26%) | catalogued as COSV52824752; called by muse, varscan2
- OR14A2 | c.838C>T p.P280S | Missense Mutation (SNP) | VAF 654/1128 reads (58%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.864); catalogued as rs1036047732; called by muse, varscan2
- PKDREJ | c.6544G>A p.V2182M | Missense Mutation (SNP) | VAF 282/756 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs767631318; called by muse, varscan2
- PRPF38A | c.671G>T p.R224L | Missense Mutation (SNP) | VAF 321/812 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.871); catalogued as COSV57123137; called by muse, varscan2
- REG3A | c.398G>T p.W133L | Missense Mutation (SNP) | VAF 280/1272 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59410776; called by muse, varscan2
- SLC12A5 | c.2901G>C p.K967N (on ENST00000454036 / NM_001134771.2; = p.K944N on NM_020708.5) | Missense Mutation (SNP) | VAF 236/1296 reads (18%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.467); catalogued as COSV99275795; called by muse, varscan2
- ABHD12 | c.425dup p.H142Qfs*20 | Frame Shift Ins (INS) | VAF 31/312 reads (10%) | called by pindel, varscan2
- ATXN2L | c.2225G>A p.G742D | Missense Mutation (SNP) | VAF 464/1076 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); called by muse, varscan2
- BRD3 | c.1208del p.K403Sfs*8 | Frame Shift Del (DEL) | VAF 226/415 reads (54%) | called by pindel, varscan2
- DENND4A | c.5391G>A p.R1797= | Splice Region (SNP) | VAF 208/530 reads (39%) | called by muse, varscan2
- DNAJC1 | c.414G>T p.Q138H | Missense Mutation (SNP) | VAF 279/968 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- EED | c.209del p.K70Rfs*16 | Frame Shift Del (DEL) | VAF 573/1098 reads (52%) | called by pindel, varscan2
- GSK3A | c.1269C>G p.F423L | Missense Mutation (SNP) | VAF 286/638 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.181); called by muse, varscan2
- KCNJ4 | c.628C>T p.R210C | Missense Mutation (SNP) | VAF 180/721 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- NUP85 | c.1517T>A p.F506Y | Missense Mutation (SNP) | VAF 96/862 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); called by muse, varscan2
- PRKCQ | c.2029T>C p.F677L | Missense Mutation (SNP) | VAF 552/932 reads (59%) | SIFT tolerated (0.65); PolyPhen benign (0); called by muse, varscan2
- SLC13A2 | c.898A>G p.I300V | Missense Mutation (SNP) | VAF 328/640 reads (51%) | SIFT tolerated (0.13); PolyPhen benign (0.065); called by muse, varscan2
- SP140 | c.1586A>C p.Q529P | Missense Mutation (SNP) | VAF 197/836 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.007); called by muse, varscan2
- TIAM2 | c.4207-2A>G p.X1403_splice (on ENST00000529824; = p.X1374_splice on NM_012454.3) | Splice Site (SNP) | VAF 118/650 reads (18%) | called by muse, varscan2
- UBXN11 | c.69T>G p.P23= | Splice Region (SNP) | VAF 75/444 reads (17%) | called by muse, varscan2
- ZNF469 | c.10894G>T p.G3632W (on ENST00000437464; = p.G3660W on NM_001367624.2) | Missense Mutation (SNP) | VAF 104/844 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, varscan2
- BRD3 | c.1194G>C p.V398= | Silent (SNP) | VAF 298/359 reads (83%) | called by muse, varscan2
- CFAP74 | c.603C>T p.R201= | Silent (SNP) | VAF 82/374 reads (22%) | catalogued as rs969683540; called by muse, varscan2
- CORO2A | c.126C>T p.A42= | Silent (SNP) | VAF 366/444 reads (82%) | catalogued as rs375207574; called by muse, varscan2
- DNHD1 | c.3927G>C p.L1309= | Silent (SNP) | VAF 198/854 reads (23%) | called by muse, varscan2
- GRAMD4 | c.1602G>A p.G534= | Silent (SNP) | VAF 162/858 reads (19%) | called by muse, varscan2
- ITGB2 | c.855C>A p.R285= | Silent (SNP) | VAF 204/638 reads (32%) | called by muse, varscan2
- ZNF534 | c.22T>C p.L8= | Silent (SNP) | VAF 135/468 reads (29%) | catalogued as COSV99989945; called by muse, varscan2
- KCNC2 | c.*771C>G | 3'UTR (SNP) | VAF 251/959 reads (26%) | called by muse, varscan2
- KIF1B | c.2115+5934C>T | Intron (SNP) | VAF 86/516 reads (17%) | catalogued as rs1222194805; called by muse, varscan2
- KLC1 | c.*6044G>A | 3'UTR (SNP) | VAF 80/636 reads (13%) | called by muse, varscan2
- MAX | c.-3G>A | 5'UTR (SNP) | VAF 396/966 reads (41%) | called by muse, varscan2
- MS4A1 | c.-45C>A | 5'UTR (SNP) | VAF 450/703 reads (64%) | called by muse, varscan2
- MST1 | c.*7C>A | 3'UTR (SNP) | VAF 468/877 reads (53%) | called by muse, varscan2
- MUC4 | c.15509-61C>A | Intron (SNP) | VAF 164/295 reads (56%) | called by muse, varscan2
- QKI | c.143-28A>G | Intron (SNP) | VAF 94/454 reads (21%) | called by muse, varscan2
- RPL3 | c.689-32C>T | Intron (SNP) | VAF 311/576 reads (54%) | catalogued as rs745540633, COSV53366772; called by muse, varscan2
